Somatic mutation profile of tumor specimen TCGA-BR-7197-01A (aliquot TCGA-BR-7197-01A-11D-2201-08) from TCGA case TCGA-BR-7197, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: GX; Age at diagnosis: 69.7 years (25,445 days).
Specimen TCGA-BR-7197-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7953fafd-cd6b-4655-80e8-394ba58fd757.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-7197-10A (Blood Derived Normal), aliquot TCGA-BR-7197-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6191e27-3081-48e6-8433-cb7c89c16082

The open-access MAF lists 186 somatic variants for this specimen: 141 protein-altering or splice-affecting, 38 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 38, Nonsense Mutation 9, Intron 3, Splice Site 2, Frame Shift Del 2, RNA 2, Frame Shift Ins 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as rs137854568, CM910029, COSV57324169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB4 | c.3668A>C p.K1223T | Missense Mutation (SNP) | VAF 66/245 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as COSV61475135, COSV61522424, COSV61527805; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTPA | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs35916840, CM981967; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.13972T>A p.F4658I | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV68944732, COSV68947840; called by muse, mutect2, varscan2
- ABCF1 | c.880C>T p.R294C (on ENST00000326195 / NM_001025091.2; = p.R256C on NM_001090.3) | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58228271; called by muse, mutect2, varscan2
- ABCF2 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.836); catalogued as rs745724501, COSV55181668; called by muse, mutect2, varscan2
- ADAMTS16 | c.2227T>C p.S743P | Missense Mutation (SNP) | VAF 128/219 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV56982957, COSV57000682, COSV99943085; called by muse, mutect2, varscan2
- ADAMTS5 | c.587A>G p.E196G | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV53177162; called by muse, mutect2, varscan2
- ADAMTS5 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV53177106; called by muse, mutect2
- ADGRB3 | c.3916A>C p.S1306R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as COSV53238922, COSV53240852; called by muse, mutect2, varscan2
- AOX1 | c.1985T>C p.F662S | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV65980765; called by muse, mutect2, varscan2
- ASCC3 | c.6196C>T p.R2066* | Nonsense Mutation (SNP) | VAF 16/114 reads (14%) | catalogued as COSV64973311; called by muse, mutect2, varscan2
- ATP2B2 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs375973812; called by muse, mutect2, varscan2
- BCAT2 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV60272101; called by muse, mutect2, varscan2
- BHLHE40 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV56575152; called by muse, mutect2, varscan2
- BIRC2 | c.575A>G p.H192R | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs182528901, COSV57160905; called by muse, mutect2, varscan2
- BRAT1 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV61394710; called by muse, mutect2, varscan2
- CAP1 | c.1057A>T p.I353L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as COSV61223025; called by muse, mutect2, varscan2
- CDH11 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs757580985, COSV51755495; called by muse, mutect2, varscan2
- CEP290 | c.433A>G p.N145D | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58350075; called by muse, mutect2, varscan2
- CHD8 | c.6104G>A p.R2035Q (on ENST00000646647 / NM_001170629.2; = p.R1756Q on NM_020920.4) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs374379959; called by muse, mutect2, varscan2
- CHERP | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.885); catalogued as rs766515661, COSV52223206, COSV52227487; called by muse, mutect2, varscan2
- CLEC2D | c.523A>G p.R175G | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV51992942; called by muse, mutect2, varscan2
- CNGA4 | c.1529A>C p.K510T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV66005440; called by muse, mutect2, varscan2
- CNTNAP1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as COSV52848813; called by muse, mutect2, varscan2
- CNTNAP5 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.498); catalogued as COSV101443000, COSV70478849; called by muse, mutect2, varscan2
- COL4A4 | c.3778C>T p.P1260S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.34); catalogued as COSV61630579; called by muse, mutect2, varscan2
- CORO7 | c.1781C>T p.T594M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs201451820, COSV52028835; called by muse, mutect2, varscan2
- CPED1 | c.2107T>C p.S703P | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV59999052; called by muse, mutect2, varscan2
- CSTF1 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs1421239466, COSV53858263; called by muse, mutect2, varscan2
- CUBN | c.2170T>G p.L724V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV64711059; called by muse, mutect2, varscan2
- DCSTAMP | c.902T>G p.L301R | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52576825, COSV99886075; called by muse, mutect2, varscan2
- DGKB | c.725A>C p.D242A | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1222776325, COSV51769857; called by muse, mutect2
- DNAH6 | c.1812T>G p.I604M | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as COSV99408485; called by muse, mutect2, varscan2
- DOCK10 | c.2804A>T p.K935M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.718); catalogued as COSV51362317; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.941); catalogued as rs1272049855, COSV62566990; called by muse, mutect2, varscan2
- ERCC6L2 | c.1505C>G p.S502C | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV56629253; called by muse, mutect2, varscan2
- ERF | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55895314; called by muse, mutect2, varscan2
- ESF1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV52519858; called by muse, mutect2, varscan2
- F13A1 | c.2082A>C p.E694D | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV53555871; called by muse, mutect2, varscan2
- FAM47C | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.093); catalogued as rs140469750, COSV63724403; called by muse, varscan2
- FIG4 | c.949A>C p.S317R | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57785968; called by muse, mutect2, varscan2
- FILIP1 | c.563A>T p.H188L | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV52725531; called by muse, mutect2, varscan2
- FREM2 | c.7621A>C p.K2541Q | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV54832338; called by muse, mutect2, varscan2
- FSTL5 | c.1930G>T p.D644Y | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as rs1465288477, COSV60182091, COSV60186252; called by muse, mutect2, varscan2
- FUBP3 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as rs1434334245, COSV60513528; called by muse, mutect2, varscan2
- GAD1 | c.464A>C p.N155T | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV60151847; called by muse, mutect2, varscan2
- GALNTL6 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs146548110, COSV72490733, COSV72495008; called by muse, mutect2, varscan2
- GARNL3 | c.2282C>T p.P761L | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763785641, COSV59224764, COSV59228173; called by muse, mutect2, varscan2
- GJA8 | c.844A>C p.T282P | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.743); catalogued as COSV53787735, COSV53788247; called by muse, mutect2
- GPR26 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs1165933159, COSV52933248; called by muse, mutect2, varscan2
- HCN1 | c.783A>C p.K261N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV57500017; called by muse, mutect2, varscan2
- HFM1 | c.2680+2T>C p.X894_splice | Splice Site (SNP) | VAF 51/76 reads (67%) | catalogued as COSV54023901; called by muse, mutect2, varscan2
- HMCN1 | c.9127G>T p.E3043* | Nonsense Mutation (SNP) | VAF 100/133 reads (75%) | catalogued as COSV54878415, COSV54886798; called by muse, mutect2, varscan2
- IDO2 | c.793G>A p.G265S (on ENST00000389060; = p.G278S on NM_194294.2) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs530531915, COSV58424477; called by muse, mutect2, varscan2
- IL7R | c.1217T>G p.L406R | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.861); catalogued as COSV57405878, COSV57406361; called by muse, mutect2
- INSL5 | c.51C>G p.I17M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV58788048; called by muse, mutect2, varscan2
- ITGAV | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs200516634, COSV53710500; called by muse, mutect2, varscan2
- KAT6A | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV55904438, COSV99706198; called by muse, mutect2, varscan2
- KCNMB2 | c.380T>G p.L127R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV64200633; called by muse, mutect2, varscan2
- KLK4 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1568514332, COSV60675658; called by muse, mutect2, varscan2
- KLRD1 | c.36T>G p.I12M | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.729); catalogued as COSV60273258; called by muse, mutect2, varscan2
- LAMA1 | c.1155A>C p.K385N | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.601); catalogued as COSV67533961; called by muse, mutect2, varscan2
- LBP | c.175C>A p.L59M | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV99461240; called by muse, mutect2, varscan2
- LMBRD1 | c.871T>G p.L291V (on ENST00000649011; = p.L269V on NM_018368.4) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV65296565; called by muse, mutect2, varscan2
- LPIN3 | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.05); catalogued as COSV64717773; called by muse, mutect2, varscan2
- LRP1B | c.11836A>G p.I3946V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV67199391; called by muse, mutect2, varscan2
- LRRC27 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs755917560, COSV59807890; called by muse, mutect2, varscan2
- LRRC7 | c.4499G>A p.S1500N (on ENST00000651989 / NM_001370785.2; = p.S1420N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50427750, COSV99230326; called by muse, mutect2, varscan2
- LTO1 | c.80A>G p.Y27C | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs779459524, COSV54162733; called by muse, mutect2, varscan2
- LZTS3 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs199773308; called by muse, mutect2, varscan2
- MAP2 | c.2944G>C p.E982Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52285288; called by muse, mutect2, varscan2
- MAPK10 | c.128C>T p.A43V (on ENST00000359221 / NM_001351625.2; = p.A81V on NM_002753.5) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs143720396, COSV60378527; called by muse, mutect2, varscan2
- MCCD1 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV66018843; called by muse, mutect2, varscan2
- MCL1 | c.913T>G p.W305G | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57190090; called by muse, mutect2, varscan2
- MRPL34 | c.46G>C p.A16P | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as COSV53112693; called by muse, mutect2, varscan2
- MUC16 | c.27589A>T p.T9197S | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.022); catalogued as COSV67454097; called by muse, mutect2, varscan2
- MUC16 | c.14167G>T p.A4723S | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as COSV67454112; called by muse, mutect2, varscan2
- MYH7B | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs759861137, COSV53417758; called by muse, mutect2, varscan2
- NELL1 | c.2183T>G p.L728R | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs957167187, COSV54248990; called by muse, mutect2, varscan2
- OR51D1 | c.467A>T p.K156M | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62914000; called by muse, mutect2, varscan2
- OR52J3 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66746642; called by muse, mutect2, varscan2
- P2RX2 | c.375C>A p.C125* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV57676882; called by muse, mutect2, varscan2
- PCDH17 | c.1436T>C p.L479P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64972857; called by muse, mutect2, varscan2
- PCLO | c.8431G>A p.E2811K | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV61623653; called by muse, mutect2, varscan2
- PCLO | c.7111A>T p.K2371* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100437115; called by muse, mutect2
- PHIP | c.3928C>T p.R1310C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs369513920; called by muse, mutect2, varscan2
- POGZ | c.3023G>A p.R1008Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.072); catalogued as rs777415507, COSV51850879; called by muse, mutect2, varscan2
- POP1 | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 56/75 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV62892217; called by muse, mutect2, varscan2
- PTPRA | c.906+1G>A p.X302_splice | Splice Site (SNP) | VAF 28/190 reads (15%) | catalogued as COSV53779718; called by muse, mutect2, varscan2
- PXDNL | c.774A>C p.E258D | Missense Mutation (SNP) | VAF 112/148 reads (76%) | SIFT tolerated (0.14); PolyPhen benign (0.345); catalogued as rs767286695, COSV62483007; called by muse, mutect2, varscan2
- RBM43 | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV58878334, COSV58878504; called by muse, mutect2, varscan2
- RELN | c.1174T>C p.Y392H | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV58992328; called by muse, mutect2, varscan2
- RGS12 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.226); catalogued as rs780632548, COSV60902487; called by muse, mutect2, varscan2
- RPS6KA3 | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV65387275; called by muse, mutect2, varscan2
- RRP12 | c.3887G>A p.R1296Q | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs1214251676, COSV59666140; called by muse, mutect2, varscan2
- RTL4 | c.126A>C p.Q42H | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV61205698; called by muse, mutect2, varscan2
- SAMD8 | c.941A>T p.E314V | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65509350; called by muse, mutect2, varscan2
- SAMD9 | c.1531A>C p.S511R | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV66073810; called by muse, mutect2, varscan2
- SCN1A | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs752591998, COSV57664533; called by muse, mutect2, varscan2
- SEMA4B | c.2215C>T p.R739W | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs201550724, COSV100153378, COSV60172897; called by muse, mutect2, varscan2
- SGCE | c.440A>G p.D147G (on ENST00000647096; = p.D111G on NM_003919.3) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV56016119; called by muse, mutect2, varscan2
- SI | c.4988A>C p.K1663T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV52271089; called by muse, mutect2, varscan2
- SIGLEC10 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV59480105; called by muse, mutect2, varscan2
- SLC12A2 | c.2881G>T p.D961Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV52469577, COSV99320649; called by muse, mutect2, varscan2
- SLC25A36 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV60781555; called by muse, mutect2, varscan2
- SLC25A38 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761041331, COSV56193962; called by mutect2, varscan2
- SLC6A17 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs986450206, COSV58992014; called by muse, mutect2, varscan2
- SMC1B | c.2278C>T p.R760* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as rs764800562, COSV62528901; called by muse, mutect2, varscan2
- STK31 | c.2875A>C p.S959R | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV63454853; called by muse, mutect2, varscan2
- STX1A | c.196A>C p.N66H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.841); catalogued as COSV56108855; called by muse, mutect2
- SYNE1 | c.11846A>T p.D3949V | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV54936838, COSV99561920; called by muse, mutect2, varscan2
- TAF1B | c.1510T>G p.S504A | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV55154937; called by muse, mutect2, varscan2
- TFAM | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100876100; called by muse, mutect2, varscan2
- TLCD4 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 29/87 reads (33%) | catalogued as COSV64631575; called by muse, mutect2, varscan2
- TMEM44 | c.1150G>T p.V384L (on ENST00000392432 / NM_001166305.2; = p.V337L on NM_138399.5) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV56448031, COSV56451298, COSV56451764; called by muse, mutect2
- TNFAIP1 | c.772A>T p.T258S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV50228247; called by muse, mutect2, varscan2
- TTN | c.25712A>C p.K8571T (on ENST00000591111; = p.K7644T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | PolyPhen benign (0.194); catalogued as COSV59926486, COSV60298598; called by muse, mutect2
- TTN | c.12553A>C p.S4185R (on ENST00000591111; = p.S4139R on NM_003319.4) | Missense Mutation (SNP) | VAF 71/239 reads (30%) | catalogued as COSV59951668; called by muse, mutect2, varscan2
- UBE3C | c.1790G>A p.R597K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV61952169; called by muse, mutect2, varscan2
- UNC5D | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs770237823, COSV54779164; called by muse, mutect2, varscan2
- UTRN | c.2442C>G p.I814M | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1253305916, COSV62330526; called by muse, mutect2, varscan2
- VGLL1 | c.725T>G p.L242R | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.231); catalogued as COSV65702858; called by muse, mutect2, varscan2
- VWC2L | c.629A>C p.Q210P | Missense Mutation (SNP) | VAF 51/243 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.526); catalogued as COSV100435011, COSV56967544; called by muse, mutect2, varscan2
- WNK3 | c.5008A>C p.S1670R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63612667; called by muse, mutect2, varscan2
- WNT9A | c.527G>T p.S176I | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.158); catalogued as COSV55293776; called by muse, mutect2, varscan2
- XPO6 | c.3085G>A p.V1029M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58964595; called by muse, mutect2, varscan2
- ZNF208 | c.1715A>C p.K572T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV68107459; called by muse, mutect2, varscan2
- ZNF382 | c.324A>C p.K108N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV53086910; called by muse, mutect2, varscan2
- ZNF43 | c.20T>C p.M7T | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV61683324, COSV61684673; called by muse, mutect2, varscan2
- ZNF474 | c.794A>C p.K265T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV56945697; called by muse, mutect2, varscan2
- ZNF493 | c.539T>A p.L180H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62749510; called by muse, mutect2, varscan2
- ZSCAN10 | c.1942G>A p.A648T (on ENST00000252463; = p.A703T on NM_032805.3) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs772664359, COSV52967292; called by muse, mutect2, varscan2
- ZSCAN10 | c.1098G>C p.K366N (on ENST00000252463; = p.K421N on NM_032805.3) | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV52967303; called by muse, mutect2, varscan2
- AC245033.1 | c.1638A>C p.E546D | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ELP3 | c.436_439dup p.Q147Pfs*16 | Frame Shift Ins (INS) | VAF 52/134 reads (39%) | called by mutect2, pindel, varscan2
- ITGB4 | c.3713dup p.S1239Efs*4 | Frame Shift Ins (INS) | VAF 24/94 reads (26%) | called by mutect2, pindel, varscan2
- PPP2R3B | c.1227_1233del p.M410Sfs*47 | Frame Shift Del (DEL) | VAF 29/83 reads (35%) | called by mutect2, pindel, varscan2
- UBE2NL | c.317T>C p.L106P | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ZNF804A | c.3314_3341del p.Q1105Lfs*35 | Frame Shift Del (DEL) | VAF 9/77 reads (12%) | called by mutect2, pindel
- ARHGAP39 | c.1920C>T p.T640= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV52768341, COSV52776685; called by muse, mutect2, varscan2
- CAMK1D | c.390C>T p.D130= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs536965936, COSV66608970; called by muse, mutect2, varscan2
- CDH7 | c.1770A>G p.V590= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV59883322; called by muse, mutect2, varscan2
- CES1 | c.429G>T p.G143= | Silent (SNP) | VAF 7/179 reads (4%) | catalogued as rs758995643, COSV100828677; called by muse, mutect2
- CPED1 | c.1495C>T p.L499= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV59999032; called by muse, mutect2, varscan2
- CPED1 | c.1839T>C p.T613= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV59999041; called by muse, mutect2, varscan2
- CRTC1 | c.1542C>T p.A514= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV58717408; called by muse, mutect2
- DCC | c.2139A>T p.A713= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV100498316, COSV59092436; called by muse, mutect2, varscan2
- DYNC1I1 | c.1731G>A p.G577= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as COSV61457902; called by muse, mutect2, varscan2
- FCGR2A | c.726G>A p.R242= (on ENST00000271450 / NM_001136219.3; = p.R241= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 125/260 reads (48%) | catalogued as COSV54837666; called by muse, mutect2, varscan2
- FREM2 | c.1402T>C p.L468= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV54826828, COSV54842467; called by muse, mutect2, varscan2
- FRYL | c.1359C>T p.V453= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV51943149, COSV51953065; called by muse, mutect2, varscan2
- GRAMD2A | c.837G>A p.P279= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as rs139817220; called by muse, mutect2, varscan2
- GRIA4 | c.1692A>C p.L564= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV56887467; called by mutect2, varscan2
- GSAP | c.2223A>G p.T741= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2
- IRX1 | c.348T>G p.A116= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs1464441355, COSV57358402, COSV57358593, COSV57363094; called by muse, mutect2, varscan2
- KCNQ3 | c.930C>T p.G310= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV66466586; called by muse, mutect2, varscan2
- KCNV1 | c.309C>T p.F103= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV52085247; called by muse, mutect2, varscan2
- MUC16 | c.15255A>C p.T5085= | Silent (SNP) | VAF 93/231 reads (40%) | catalogued as COSV67454103; called by muse, mutect2, varscan2
- MYO3A | c.4002G>A p.R1334= | Silent (SNP) | VAF 24/155 reads (15%) | catalogued as COSV56324005; called by muse, mutect2, varscan2
- NDN | c.285G>A p.P95= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV59358996; called by muse, mutect2, varscan2
- NPR2 | c.1074G>A p.R358= | Silent (SNP) | VAF 47/121 reads (39%) | catalogued as COSV61309865; called by muse, mutect2, varscan2
- OR52E4 | c.168T>C p.S56= | Silent (SNP) | VAF 69/230 reads (30%) | catalogued as COSV57624233; called by muse, mutect2, varscan2
- OR8H3 | c.729T>C p.S243= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs755276730, COSV57908039, COSV57910347; called by muse, mutect2, varscan2
- PDCD11 | c.999C>T p.C333= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs745777658, COSV63933378; called by muse, mutect2, varscan2
- PIK3CB | c.552C>T p.I184= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV56684324; called by muse, mutect2, varscan2
- POMT2 | c.1521C>T p.Y507= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV55070302; called by muse, mutect2, varscan2
- RBM10 | c.339G>A p.E113= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV61308362; called by muse, mutect2, varscan2
- RPL18A | c.81C>A p.L27= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99714500; called by muse, varscan2
- ST3GAL6 | c.102G>A p.V34= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV54579989, COSV54584444; called by muse, mutect2, varscan2
- TGFBRAP1 | c.375C>T p.N125= | Silent (SNP) | VAF 42/120 reads (35%) | catalogued as rs746399074, COSV51510725; called by muse, mutect2, varscan2
- TLL2 | c.414C>T p.A138= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as rs756774672, COSV63571449; called by muse, mutect2, varscan2
- TNXB | c.9715C>A p.R3239= (on ENST00000647633; = p.R2992= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs760257516, COSV64475901; called by muse, mutect2, varscan2
- TRIO | c.8559C>T p.V2853= | Silent (SNP) | VAF 133/343 reads (39%) | catalogued as rs754497690, COSV59988552, COSV59991468; called by muse, mutect2, varscan2
- TSHZ3 | c.2520C>T p.R840= | Silent (SNP) | VAF 65/311 reads (21%) | catalogued as rs373110206; called by muse, mutect2, varscan2
- VAV3 | c.630T>G p.T210= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV58379087; called by muse, mutect2, varscan2
- ZEB2 | c.2584T>C p.L862= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV57953512, COSV57953777; called by muse, mutect2, varscan2
- ZNF831 | c.453C>T p.R151= | Silent (SNP) | VAF 102/333 reads (31%) | catalogued as rs778350290, COSV64038516, COSV64041752; called by muse, mutect2, varscan2
- GABBR2 | c.*1G>T | 3'UTR (SNP) | VAF 4/21 reads (19%) | catalogued as COSV52301988, COSV99411320; called by muse, mutect2
- MAGI1 | c.3635-1988A>C | Intron (SNP) | VAF 52/154 reads (34%) | catalogued as COSV100442967; called by muse, mutect2, varscan2
- MELTF | c.712+1684C>T | Intron (SNP) | VAF 21/81 reads (26%) | catalogued as rs751989515, COSV56383680, COSV99586557; called by muse, mutect2, varscan2
- MIR920 | n.39A>C | RNA (SNP) | VAF 28/97 reads (29%) | catalogued as COSV101290064; called by muse, mutect2, varscan2
- RPL13 | c.*1A>C | 3'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100276343; called by muse, mutect2, varscan2
- TBRG4 | c.736-215A>C | Intron (SNP) | VAF 25/83 reads (30%) | catalogued as rs767981285, COSV99345619; called by muse, mutect2, varscan2
- TUBB7P | n.243C>T | RNA (SNP) | VAF 9/73 reads (12%) | catalogued as rs782373242; called by muse, mutect2, varscan2
